TCGA case TCGA-IF-A3RQ — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Lipomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: University of Texas MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8488bb97-bf11-45cc-b1bd-52969598448d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 70 years; Vital status: Dead; Days to death: 1,129 days (3.1 years).

Diagnoses (2)
1. Dedifferentiated liposarcoma (the primary disease): ICD-O-3 morphology code: 8858/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 70.3 years (25,680 days); Year of diagnosis: 1998; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 6; Tumor length measurement: 15; Tumor width measurement: 12.
   Pathology details: Measurement type: Pathologic; Tumor burden: 15.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis percent: 5; Necrosis present: Yes; Tumor depth descriptor: Deep.
2. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma), site: Retroperitoneum. Age at diagnosis: 71.5 years (26,121 days); Days to diagnosis: 441 days (1.2 years); Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 10; Tumor length measurement: 12; Tumor width measurement: 10.
   Pathology details: Measurement type: Pathologic; Tumor burden: 30.6.
   Pathology details: Additional pathology findings: Well Differentiated.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.

Follow-up (2 entries)
- Day 441 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Retroperitoneum; Days to recurrence: 441 days (1.2 years); Discontiguous lesion count: 5.
- Days to follow up: 1,129 days (3.1 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-IF-A3RQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 50 mg.
  Slide TCGA-IF-A3RQ-01A-01-TSA: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-IF-A3RQ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-IF-A3RQ-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 130 mg.
  Slide TCGA-IF-A3RQ-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Retroperitoneum; Submitted tumor site: Retroperitoneum/Upper abdominal - Intraabdominal; Submitted tumor site: Lower abdominal/Pelvic - Pelvic.
- Primary pathology: Margin status: Negative; Tumor total necrosis: <10% (focal necrosis); Disease multifocal indicator: No; Locoregional recurrence indicator: Yes; Metastatic disease confirmed: No; Contiguous organ resection: Kidney; Contiguous organ invaded: No; Well diff liposarc prior diagnosis indicator: Yes; Days from index date to well diff liposarc resection: -3096.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic depth: 6.
- Drug treatment: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment ended: 457; Pharmaceutical therapy drug name: Adriamycin; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Partial Response.
- Drug treatment, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Radiation treatment: Days from index date to radiation therapy started: 455; Days from index date to radiation therapy ended: 523; Radiation therapy type: External; Radiation total dose: 61.8; Radiation adjuvant units: Gy; Radiation adjuvant fractions total: 27; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No; Treatment best response: Partial Response.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Patient had a prior tubular adenonoma of the colon. No radiation or systemic chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,129 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,129 days; disease-free interval: event (new tumor event after initially disease-free), 441 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 441 days.
